Gene-level copy-number profile of tumor specimen TCGA-AO-A128-01A from TCGA case TCGA-AO-A128, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.2 years (22,340 days).
Specimen TCGA-AO-A128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e704bf4e-f9a2-4ae5-a6ae-2cf62564c0ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A128-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14a640d9-c9a1-4ef6-8959-3099cc3fc2c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 633; copy number 2: 34,413; copy number 3: 5,926; copy number 4: 9,716; copy number 5: 4,036; copy number 6: 4,996; copy number 7: 97.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A128-01A-11D-A10L-01): tumor purity 0.27, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:57,890,327–57,899,162, 1 gene: LINC02225.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,129 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr3:75,906,695–77,649,964, 1 gene, copy number 5 (within-gene range 3–5): ROBO2.
- chr3:76,434,018–198,222,513, 1,890 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–40,860,763, 727 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:64,140,495–107,202,522, 856 genes, copy number 6 (broad region; genes not listed).
- chr8:37,516,399–145,066,685, 1,700 genes, copy number 5–7 (broad region; genes not listed).
- chr19:37,613,749–58,605,223, 1,351 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
